CCDI case PBBTKE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/add3eff1-0000-4f09-a331-c980e52191fb

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Alveolar soft part sarcoma: ICD-O-3 morphology code: 9581/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 14.3 years (5,228 days).

Biospecimens (3 samples)
- Sample 0DHDZG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHDZP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHE08: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
